Somatic mutation profile of tumor specimen TCGA-XF-AAMH-01A (aliquot TCGA-XF-AAMH-01A-11D-A42E-08) from TCGA case TCGA-XF-AAMH, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 80.9 years (29,547 days).
Specimen TCGA-XF-AAMH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2de7a79-d6d6-4e15-beb6-f053e1307c1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAMH-10A (Blood Derived Normal), aliquot TCGA-XF-AAMH-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45aa6be2-0344-440e-bad9-71e31fc37e92

The open-access MAF lists 69 somatic variants for this specimen: 52 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 38, Silent 17, Frame Shift Del 6, Nonsense Mutation 6, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 26/59 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCNN1A | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs137852635, CM993904, COSV57435063; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.3067C>T p.R1023* | Nonsense Mutation (SNP) | VAF 18/87 reads (21%) | catalogued as rs773986908, COSV100382825, COSV100382832; called by muse, mutect2, varscan2
- ADARB2 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.241); catalogued as COSV67220676; called by muse, mutect2, varscan2
- AFG3L2 | c.1408G>T p.D470Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52313972, COSV52317336; called by muse, mutect2
- AP3B1 | c.3253C>T p.R1085W | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1243796647, COSV54881714; called by muse, mutect2, varscan2
- CAMSAP2 | c.2649_2655del p.N884Efs*4 (on ENST00000236925 / NM_001297707.2; = p.N873Efs*4 on NM_203459.3) | Frame Shift Del (DEL) | VAF 38/123 reads (31%) | catalogued as COSV52669380; called by mutect2, pindel, varscan2
- CCDC77 | c.1249G>T p.V417L | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV53472586; called by muse, mutect2, varscan2
- DHX8 | c.3259G>A p.D1087N | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as rs1467658871, COSV52252709; called by muse, mutect2, varscan2
- DLEC1 | c.728T>A p.V243D | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.137); catalogued as COSV57298349; called by muse, mutect2, varscan2
- DYSF | c.1922T>C p.V641A | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50295846; called by muse, mutect2, varscan2
- EIF6 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs1373667988, COSV65582754; called by muse, mutect2, varscan2
- EPHA2 | c.1243del p.R415Afs*8 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | catalogued as COSV100626069; called by mutect2, pindel, varscan2
- FAM170A | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.629); catalogued as COSV58924765; called by muse, mutect2, varscan2
- FAM20A | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 14/87 reads (16%) | catalogued as COSV99873251; called by muse, mutect2, varscan2
- GJA5 | c.1021A>G p.K341E | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV54783694; called by muse, mutect2, varscan2
- GRIA1 | c.277A>C p.T93P | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV53598678; called by muse, mutect2, varscan2
- GRID1 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as rs375277319; called by muse, mutect2, varscan2
- KBTBD3 | c.652G>A p.V218I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV73241346; called by muse, mutect2, varscan2
- KLF5 | c.1253A>G p.D418G | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV66614131, COSV66614346; called by muse, mutect2, varscan2
- LUM | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs745337639, COSV57127951; called by muse, mutect2, varscan2
- MYO5B | c.4756G>T p.D1586Y | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53216263; called by muse, mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 21/66 reads (32%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NR1I2 | c.1053A>G p.P351= | Splice Region (SNP) | VAF 24/55 reads (44%) | catalogued as rs1478426691, COSV61978047; called by muse, mutect2, varscan2
- OR4K5 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1242254860, COSV60003136; called by muse, mutect2, varscan2
- OR51B5 | c.763G>T p.G255* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100332485, COSV56175061; called by muse, mutect2, varscan2
- PCBP1 | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs1212817547, COSV57850247; called by muse, mutect2, varscan2
- PPP4R4 | c.1019A>G p.Y340C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1566683340, COSV58553794; called by muse, mutect2, varscan2
- PRLHR | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as rs1190636703, COSV53303610, COSV53305030; called by muse, mutect2, varscan2
- PTGER2 | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99817386; called by muse, mutect2
- PTPN3 | c.1222G>T p.E408* | Nonsense Mutation (SNP) | VAF 21/37 reads (57%) | catalogued as COSV99355527; called by muse, mutect2, varscan2
- RASGRF2 | c.1810T>C p.S604P | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV54127703; called by muse, mutect2, varscan2
- RXRA | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs777558913, COSV62683418; called by muse, mutect2, varscan2
- SEC16A | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs780590882, COSV51525703, COSV99256731; called by muse, mutect2, varscan2
- SEMG2 | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV65647384; called by muse, mutect2, varscan2
- SHOX2 | c.17C>A p.A6E | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs1446618215, COSV55826991; called by muse, mutect2, varscan2
- SIRPA | c.1365C>A p.S455R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV61537913; called by muse, mutect2, varscan2
- SLC25A12 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as rs770856651, COSV55532728; called by muse, mutect2, varscan2
- SLC2A3 | c.59G>A p.G20D | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50001556, COSV99306364; called by muse, mutect2
- SLC37A2 | c.1318G>A p.G440S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1253530809, COSV53521681; called by muse, mutect2
- TEX10 | c.71A>G p.K24R | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1188891251, COSV100887657; called by muse, mutect2
- ULK4 | c.1760C>T p.T587I | Missense Mutation (SNP) | VAF 57/124 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV57205606; called by muse, mutect2, varscan2
- USP24 | c.5800C>T p.R1934* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV53761414; called by muse, mutect2, varscan2
- ZC3H13 | c.2256_2259del p.R753Kfs*111 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs774748324; called by mutect2, varscan2
- ZFYVE26 | c.6596C>T p.P2199L | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1458567181, COSV61327126; called by muse, mutect2, varscan2
- ZNF275 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 46/51 reads (90%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs782516737, COSV64703952; called by muse, mutect2, varscan2
- ZNF780A | c.1909G>A p.G637S | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.618); catalogued as rs890551962, COSV61815147; called by muse, mutect2, varscan2
- ZNF783 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.723); catalogued as rs776758993, COSV65185208; called by muse, mutect2, varscan2
- AGFG1 | c.907del p.Q303Rfs*31 | Frame Shift Del (DEL) | VAF 24/79 reads (30%) | called by mutect2, pindel, varscan2
- HGS | c.1660del p.V554Sfs*56 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- KANK1 | c.3546_3550dup p.A1184Efs*45 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- AGMO | c.483A>G p.R161= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as COSV61110415; called by muse, mutect2, varscan2
- C10orf90 | c.303G>T p.A101= | Silent (SNP) | VAF 46/97 reads (47%) | catalogued as COSV52950322, COSV52953271; called by muse, mutect2, varscan2
- EIF5B | c.1875C>T p.N625= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs753098187, COSV56812399; called by muse, mutect2
- GNAZ | c.648C>T p.F216= | Silent (SNP) | VAF 81/194 reads (42%) | catalogued as rs879063101, COSV50737601; called by muse, mutect2, varscan2
- GRIA2 | c.1839G>T p.S613= | Silent (SNP) | VAF 50/121 reads (41%) | catalogued as rs575418041, COSV52387798, COSV52403328; called by muse, mutect2, varscan2
- IKZF1 | c.1536G>A p.G512= | Silent (SNP) | VAF 17/26 reads (65%) | catalogued as rs1488341832, COSV58784488; called by muse, mutect2, varscan2
- KIAA2026 | c.111G>A p.Q37= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs1052139586, COSV99424046; called by muse, mutect2, varscan2
- KIF16B | c.507C>T p.T169= | Silent (SNP) | VAF 46/100 reads (46%) | catalogued as COSV61704855; called by muse, mutect2, varscan2
- MAST4 | c.2877C>T p.S959= (on ENST00000403625 / NM_001164664.2; = p.S770= on NM_015183.3) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV55122028; called by muse, varscan2
- MIOS | c.279T>C p.G93= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV60767993; called by muse, mutect2, varscan2
- MSS51 | c.966A>T p.T322= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV55019019; called by muse, mutect2, varscan2
- SERBP1 | c.129G>A p.G43= | Silent (SNP) | VAF 4/74 reads (5%) | catalogued as COSV63413734; called by muse, mutect2
- SIRPB1 | c.588C>T p.N196= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as rs371319948; called by muse, mutect2, varscan2
- TLR8 | c.1992G>A p.A664= (on ENST00000218032 / NM_138636.5; = p.A682= on NM_016610.4) | Silent (SNP) | VAF 32/34 reads (94%) | catalogued as COSV54317375; called by muse, mutect2, varscan2
- TMPRSS7 | c.1818C>T p.I606= (on ENST00000452346; = p.I480= on NM_001042575.2) | Silent (SNP) | VAF 4/98 reads (4%) | catalogued as COSV101340100; called by muse, mutect2
- TNFRSF10A | c.48G>A p.V16= | Silent (SNP) | VAF 14/15 reads (93%) | catalogued as rs200751584, COSV55325501; called by muse, varscan2
- ZNF462 | c.5721G>A p.L1907= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV52935552; called by muse, mutect2, varscan2
